MMRF case MMRF_1179 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/734e8d43-2ede-4f66-9c75-5995fb16c275

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.4 years (29,365 days); ISS stage: II; Days to last known disease status: 1,661 days (4.5 years); Days to last follow up: 1,661 days (4.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 269 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,024 days (2.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 687 days (1.9 years); Days to treatment end: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 715 days (2.0 years); Days to treatment end: 799 days (2.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 799 days (2.2 years); Days to treatment end: 1,024 days (2.8 years).
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 843 days (2.3 years); Days to treatment end: 1,024 days (2.8 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,087 days (3.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,356 days (3.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,661.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 0): M Protein 3.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.595 mg/dL; Immunoglobulin G 2.77 g/L; Immunoglobulin A 40.1 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 5.29 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 9.1 g/dL; Glucose 6.99 mmol/L.
- Day 100: M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 6.33 mmol/L.
- Day 164 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Glucose 6.05 mmol/L.
- Day 255: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 6.58 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 5.83 mmol/L.
- Day 345: Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.814 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 6.05 mmol/L.
- Day 463 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.969 mg/dL; Immunoglobulin G 6.06 g/L; Immunoglobulin A 7.22 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 6.77 mmol/L.
- Day 556 (ECOG 0): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.882 mg/dL; Immunoglobulin G 4.62 g/L; Immunoglobulin A 7.5 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 6 g/dL; Glucose 4.95 mmol/L.
- Day 641 (ECOG 0): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.825 mg/dL; Immunoglobulin G 3.88 g/L; Immunoglobulin A 11.1 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 6.88 mmol/L.
- Day 710 (ECOG 0): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.072 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 14.1 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 9.19 mmol/L.
- Day 794 (ECOG 0): M Protein 0.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 2.58 g/L; Immunoglobulin A 12.2 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.45 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 907 (ECOG 0): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.471 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 14.2 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 7.26 mmol/L.
- Day 975 (ECOG 1): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 56.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.612 mg/dL; Immunoglobulin G 4 g/L; Immunoglobulin A 14.6 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.33 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 1,087 (ECOG 0): M Protein 1.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 89.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.692 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 20.7 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 7.65 mmol/L.
- Day 1,143 (ECOG 1): M Protein 1.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.068 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 16.3 g/L; Immunoglobulin M 0.02 g/L; Lactate Dehydrogenase 5.43 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 1,258 (ECOG 0): M Protein 1.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.072 mg/dL; Immunoglobulin G 2.16 g/L; Immunoglobulin A 25.1 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 8.31 mmol/L.
- Day 1,356 (ECOG 2): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.096 mg/dL; Immunoglobulin G 1.45 g/L; Immunoglobulin A 23.5 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 6.5 g/dL; Glucose 8.31 mmol/L.
- Day 1,426 (ECOG 2): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 1.56 g/L; Immunoglobulin A 14 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 14.2 ×10⁹/L; Absolute Neutrophil 12.7 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 26 g/L; Total Protein 5.9 g/dL; Glucose 9.46 mmol/L.
- Day 1,517: M Protein 0.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.109 mg/dL; Immunoglobulin G 2.03 g/L; Immunoglobulin A 10.7 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 11.1 mmol/L.
- Day 1,641: M Protein 0.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.177 mg/dL; Immunoglobulin G 2.08 g/L; Immunoglobulin A 10.2 g/L; Immunoglobulin M 0.62 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 8.7 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 30 g/L; Total Protein 5.7 g/dL; Glucose 7.87 mmol/L.

Other clinical attributes
- Day -2: Weight: 67 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1179_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1179_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
- Sample MMRF_1179_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,087 days (3.0 years).
